Somatic mutation profile of tumor specimen ALCH-B1WX-TTP1-A (aliquot ALCH-B1WX-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1WX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 60.5 years (22,091 days).
Specimen ALCH-B1WX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 120ad767-8978-4da9-aec3-0523bb0ad60f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1WX-NB1-A (Blood Derived Normal), aliquot ALCH-B1WX-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee341983-ab64-42fc-b10e-e883c4d55b7d

The open-access MAF lists 130 somatic variants for this specimen: 90 protein-altering or splice-affecting, 21 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 21, Intron 10, RNA 6, Nonsense Mutation 5, Frame Shift Del 5, Nonstop Mutation 1, 5'UTR 1, 3'UTR 1, Splice Site 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by mutect2, varscan2
- ADHFE1 | c.850A>G p.I284V | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs777605571; called by muse, mutect2, varscan2
- AK4 | c.211C>A p.R71S | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as rs929965584; called by muse, mutect2, varscan2
- ANKRD18A | c.2839G>A p.E947K | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV57636070; called by muse, varscan2
- CD163L1 | c.3502G>T p.G1168C | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.937); catalogued as COSV58013409, COSV58018076; called by mutect2, varscan2
- CLVS1 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.17); catalogued as rs368485692; called by muse, mutect2, varscan2
- CNTNAP2 | c.1326G>T p.M442I | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV62179727, COSV62201657; called by muse, varscan2
- DPYS | c.1367C>T p.T456M | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs113309169; called by muse, mutect2
- EFCAB2 | c.810A>G p.*270Wext*5 (on ENST00000366522; = p.*134Wext*5 on NM_001143943.1) | Nonstop Mutation (SNP) | VAF 3/19 reads (16%) | catalogued as rs1218866620, COSV63659826; called by mutect2, varscan2
- EGF | c.509+1G>A p.X170_splice | Splice Site (SNP) | VAF 6/42 reads (14%) | catalogued as COSV54479697; called by muse, varscan2
- FGF20 | c.173C>A p.A58E | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51660935; called by muse, mutect2, varscan2
- GRM5 | c.976A>G p.T326A | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100554258; called by muse, mutect2, varscan2
- GTPBP8 | c.328C>G p.R110G | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.062); catalogued as COSV55607582; called by muse, mutect2
- LRRC4C | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as COSV53436303; called by muse, mutect2, varscan2
- MAP7D2 | c.415C>A p.Q139K | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs1422314573; called by muse, mutect2
- NAV3 | c.5630C>A p.S1877Y (on ENST00000397909 / NM_001024383.2; = p.S1855Y on NM_014903.6) | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99886492; called by muse, mutect2, varscan2
- NR2C1 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs746288815, COSV58010244; called by muse, mutect2, varscan2
- NTRK3 | c.1639G>T p.G547* | Nonsense Mutation (SNP) | VAF 10/127 reads (8%) | catalogued as COSV100712177; called by muse, mutect2
- OPA3 | c.302A>G p.Y101C | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs757195041; called by muse, mutect2, varscan2
- OR51B6 | c.83C>A p.P28Q | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs770496406; called by muse, mutect2, varscan2
- PCDH11X | c.4001C>A p.P1334Q | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as COSV100009965, COSV53445042, COSV53490727; called by muse, mutect2
- PCDHB7 | c.1955G>T p.R652L | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.037); catalogued as rs1319200311, COSV50763323; called by muse, mutect2
- PDZRN4 | c.2812G>T p.G938W (on ENST00000402685 / NM_001164595.2; = p.G680W on NM_013377.4) | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54213961; called by muse, mutect2
- PRAMEF4 | c.790A>T p.T264S | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV99340385; called by muse, varscan2
- PRDM16 | c.581A>G p.Y194C | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54611402; called by muse, varscan2
- PTEN | c.976G>C p.D326H | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM071949, COSV64296353, COSV64297833; called by muse, mutect2, varscan2
- PTK7 | c.1562C>T p.T521M | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs376445655; called by muse, mutect2, varscan2
- RELN | c.6146C>A p.A2049E | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as rs374232523; called by muse, mutect2, varscan2
- RYR2 | c.7867C>A p.L2623M | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV63676426; called by muse, varscan2
- SDK2 | c.6262C>T p.R2088W | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs746513867; called by muse, varscan2
- SH2D1A | c.158C>A p.T53K | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM994330; called by muse, mutect2, varscan2
- SRRM4 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as rs369698646, COSV99938694; called by muse, mutect2, varscan2
- TAF1L | c.1364G>T p.W455L | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99644297; called by muse, mutect2, varscan2
- TMCO5A | c.176T>C p.V59A | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60464948; called by muse, mutect2, varscan2
- TRIB2 | c.784C>T p.L262F | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1418882971, COSV99331009; called by muse, mutect2
- TRIM64B | c.1138T>A p.S380T | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.098); catalogued as rs1247663465; called by muse, mutect2
- VWA5B1 | c.2841G>T p.Q947H (on ENST00000375079; = p.Q948H on NM_001039500.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV57052407; called by muse, mutect2
- ZNF443 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.792); catalogued as rs374780459; called by muse, mutect2
- AGL | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ARL8A | c.161del p.G54Vfs*12 | Frame Shift Del (DEL) | VAF 10/87 reads (11%) | called by mutect2, pindel, varscan2
- BCO2 | c.690C>A p.D230E | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.217); called by mutect2, varscan2
- BLCAP | c.77C>A p.S26Y | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- BPIFB4 | c.1225C>A p.L409M | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CATSPERD | c.576A>T p.A192= | Splice Region (SNP) | VAF 14/92 reads (15%) | called by muse, mutect2, varscan2
- CPT1C | c.204del p.I69Sfs*13 | Frame Shift Del (DEL) | VAF 21/96 reads (22%) | called by mutect2, pindel, varscan2
- CYTL1 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2
- EIF3K | c.629_638del p.V210Afs*16 | Frame Shift Del (DEL) | VAF 15/141 reads (11%) | called by mutect2, pindel
- EXOC2 | c.81G>T p.R27S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GDF11 | c.1016_1031del p.N339Sfs*139 | Frame Shift Del (DEL) | VAF 3/26 reads (12%) | called by mutect2*, pindel
- GNA14 | c.496C>A p.P166T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, varscan2
- GON4L | c.1845G>T p.E615D | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GP2 | c.722G>A p.C241Y (on ENST00000381362 / NM_001007240.3; = p.C238Y on NM_001502.4) | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GPD2 | c.1013G>A p.G338E | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- INPP4B | c.1078C>T p.L360F | Missense Mutation (SNP) | VAF 54/76 reads (71%) | SIFT tolerated (0.71); PolyPhen benign (0.015); called by muse, varscan2
- ITGA11 | c.1109G>T p.G370V | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPR1 | c.4757G>T p.R1586L (on ENST00000354582; = p.R1571L on NM_002222.7) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ITPRID1 | c.3159T>A p.F1053L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.3); called by muse, varscan2
- KRTAP16-1 | c.1112C>G p.P371R | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- LRP2 | c.13331G>T p.G4444V | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.045); called by muse, varscan2
- MAP1A | c.2721C>G p.F907L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- MAP1A | c.3196C>A p.P1066T | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); called by muse, varscan2
- MDN1 | c.10199T>A p.L3400Q | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, varscan2
- MGMT | c.51G>T p.Q17H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- MMP16 | c.1558G>T p.G520* | Nonsense Mutation (SNP) | VAF 14/59 reads (24%) | called by muse, varscan2
- NAP1L2 | c.97C>A p.R33S | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- NSD3 | c.2468C>T p.P823L | Missense Mutation (SNP) | VAF 124/163 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- ONECUT2 | c.1382A>T p.Q461L | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- PAGE2B | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- PCDH15 | c.5150C>A p.P1717H | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious, low confidence (0.05); called by muse, mutect2, varscan2
- PLS1 | c.338G>A p.S113N | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- POU2AF1 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- RBM12B | c.851T>G p.F284C | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); called by muse, mutect2
- REG3G | c.395C>A p.A132E | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); called by muse, varscan2
- SATL1 | c.1441G>T p.G481W (on ENST00000395409; = p.G668W on NM_001367857.2) | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SH3RF2 | c.1380A>T p.L460F | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC17A3 | c.814G>T p.G272* | Nonsense Mutation (SNP) | VAF 9/102 reads (9%) | called by muse, mutect2
- SLC46A2 | c.350T>C p.L117P | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SPAG17 | c.2967C>A p.Y989* | Nonsense Mutation (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- SPATA7 | c.1215+1dup | Frame Shift Ins (INS) | VAF 13/83 reads (16%) | called by mutect2, pindel, varscan2
- SRBD1 | c.1415G>T p.R472I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TAS2R3 | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.104); called by muse, varscan2
- TMCC1 | c.1773C>G p.N591K (on ENST00000393238 / NM_001349268.2; = p.N267K on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2
- TMEM239 | c.560C>A p.P187Q (on ENST00000361033 / NM_001318207.1; = p.P144Q on NM_001167670.3) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TMEM54 | c.542C>A p.T181N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- TPTE | c.512T>A p.L171Q (on ENST00000618007 / NM_199261.4; = p.L153Q on NM_199259.4) | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- TUFM | c.281A>G p.K94R | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.094); called by muse, mutect2
- VAX1 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.34); called by mutect2, varscan2
- ZC3H12A | c.151A>T p.K51* | Nonsense Mutation (SNP) | VAF 61/231 reads (26%) | called by muse, mutect2, varscan2
- ZFR2 | c.1687_1688delinsA p.A563Tfs*91 | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | called by pindel, varscan2*
- ZNF350 | c.623G>T p.C208F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AMOT | c.606A>T p.P202= | Silent (SNP) | VAF 5/54 reads (9%) | called by mutect2, varscan2
- ANTXRL | c.1278G>C p.V426= | Silent (SNP) | VAF 16/120 reads (13%) | called by muse, varscan2
- BIRC6 | c.753G>A p.V251= | Silent (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- CD5 | c.657C>A p.G219= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as rs1166176493; called by muse, mutect2, varscan2
- CLPTM1L | c.1239C>T p.V413= | Silent (SNP) | VAF 8/111 reads (7%) | catalogued as rs1325733395, COSV57990148; called by muse, mutect2
- FGFR1 | c.372C>G p.S124= | Silent (SNP) | VAF 200/281 reads (71%) | called by muse, varscan2
- GABRG2 | c.810C>G p.G270= (on ENST00000361925 / NM_001375343.1; = p.G230= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/184 reads (8%) | catalogued as COSV62716657; called by muse, mutect2
- GALNTL5 | c.762C>T p.P254= | Silent (SNP) | VAF 24/155 reads (15%) | called by muse, mutect2, varscan2
- GIMD1 | c.411T>A p.A137= | Silent (SNP) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- HECTD4 | c.11745G>C p.A3915= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV66397358; called by mutect2, varscan2
- ITPRID2 | c.2886G>A p.Q962= | Silent (SNP) | VAF 12/77 reads (16%) | called by mutect2, varscan2
- KNDC1 | c.4011G>A p.R1337= | Silent (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- MAMLD1 | c.1821T>A p.P607= | Silent (SNP) | VAF 8/107 reads (7%) | called by muse, mutect2
- MTO1 | c.705G>A p.L235= | Silent (SNP) | VAF 11/126 reads (9%) | catalogued as COSV64773310; called by muse, mutect2
- NR1H4 | c.1014G>T p.A338= (on ENST00000551379 / NM_001206993.2; = p.A324= on NM_005123.4) | Silent (SNP) | VAF 16/154 reads (10%) | catalogued as COSV51849780; called by muse, varscan2
- PLCL1 | c.2943C>A p.L981= | Silent (SNP) | VAF 57/154 reads (37%) | catalogued as COSV70827625; called by muse, mutect2, varscan2
- SETBP1 | c.2985G>T p.P995= | Silent (SNP) | VAF 26/229 reads (11%) | catalogued as COSV56330438; called by muse, mutect2, varscan2
- SYNJ1 | c.2637G>T p.T879= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as rs746832641, COSV59157272; called by muse, mutect2, varscan2
- TCTEX1D1 | c.57G>T p.G19= | Silent (SNP) | VAF 6/61 reads (10%) | called by muse, varscan2
- TNS1 | c.1152C>T p.A384= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as rs1166657902; called by muse, mutect2
- TPP2 | c.2157T>A p.T719= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs1354760566; called by muse, mutect2, varscan2
- AMT | c.339+12T>C | Intron (SNP) | VAF 26/104 reads (25%) | called by muse, mutect2, varscan2
- ANKRD20A8P | n.1429G>T | RNA (SNP) | VAF 10/171 reads (6%) | catalogued as COSV101427283; called by muse, mutect2
- BUD31 | c.94+568C>G | Intron (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- CEROX1 | n.3162T>G | RNA (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2
- CLEC16A | c.2641+15del | Intron (DEL) | VAF 11/111 reads (10%) | called by mutect2, pindel, varscan2
- COL3A1 | c.282+12G>C | Intron (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2
- DST | c.4296+111del | Intron (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel
- DST | c.414+6957_414+6969del | Intron (DEL) | VAF 8/51 reads (16%) | called by mutect2, pindel, varscan2
- FAM90A27P | n.371C>A | RNA (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2, varscan2
- KRT8P11 | n.1067G>T | RNA (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- MT3 | chr16:56589139 G>A | 5'Flank (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
- NOSTRIN | c.-2A>T | 5'UTR (SNP) | VAF 33/156 reads (21%) | called by muse, varscan2
- OR10AB1P | n.915T>C | RNA (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- PCCB | c.373-135T>C | Intron (SNP) | VAF 4/26 reads (15%) | catalogued as rs1463198745; called by muse, varscan2
- PRMT8 | c.418-915G>C | Intron (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- PTPRK | c.100+1225C>T | Intron (SNP) | VAF 21/132 reads (16%) | called by muse, mutect2, varscan2
- RALYL | c.-24+551C>A | Intron (SNP) | VAF 10/96 reads (10%) | catalogued as COSV101569423; called by muse, mutect2, varscan2
- TAFA1 | c.*35C>T | 3'UTR (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- TUBB7P | n.486G>A | RNA (SNP) | VAF 19/103 reads (18%) | called by muse, mutect2, varscan2
